RC case RC-B666 — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2865bf11-a39f-4696-adb5-347d284ce6b1

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Year of birth: 1953; Vital status: Dead; Days to death: 1,841 days (5.0 years); Year of death: 2016.

Diagnoses (2)
1. T-cell large granular lymphocytic leukemia (the primary disease): ICD-O-3 morphology code: 9831/3; ICD-10 code: C84; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Blood; Classification of tumor: primary; Age at diagnosis: 58.0 years (21,191 days); Year of diagnosis: 2011; Method of diagnosis: Blood Draw; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Ann Arbor extranodal involvement: Yes; International Prognostic Index (IPI): Low Risk; Sites of involvement: Peripheral blood.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Methotrexate; Initial disease status: Initial Diagnosis; Days to treatment start: 544 days (1.5 years); Days to treatment end: 1,104 days (3.0 years); Treatment outcome: Stable Disease; Reason treatment ended: Other; Timepoint category: First Treatment.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide; Initial disease status: Initial Diagnosis; Days to treatment start: 1,096 days (3.0 years); Days to treatment end: 1,400 days (3.8 years); Treatment outcome: Progressive Disease; Reason treatment ended: Disease Progression; Timepoint category: Post Initial Treatment.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Alemtuzumab; Initial disease status: Progressive Disease; Days to treatment start: 1,524 days (4.2 years); Days to treatment end: 1,757 days (4.8 years); Treatment outcome: Partial Response; Reason treatment ended: Other; Timepoint category: Post Initial Treatment; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Organ Transplantation.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Stable Disease; Timepoint category: Postoperative.
   Recorded as not given: adjuvant Radiation Therapy, NOS, postoperative; Stem Cell Transplantation, Allogeneic; Stem Cell Transplantation, Autologous; Stem Cell Transplantation, NOS.
2. Progression (histology not recorded by GDC). Age at diagnosis: 61.9 years (22,611 days); Days to diagnosis: 1,420 days (3.9 years).

Follow-up (3 entries)
- Day 1,420 (progression): Progression or recurrence: Yes; Days to progression: 1,420 days (3.9 years).
- Days to follow up: 1,732 days (4.7 years); Disease response: Partial Response.
- Day 1,841 (end of treatment course 1): Disease response: Partial Response.

Molecular and laboratory tests
- Epstein-Barr Virus: Positive [Test analyte type: DNA].
- Lactate Dehydrogenase 192 U/L [Blood test normal range upper: 250].
- Epstein-Barr Virus (ISH): Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 85.9 kg; Height: 177.5 cm; BMI: 27.3.
- Timepoint category: Prior to Diagnosis; Comorbidities: Organ Transplant (Site) / Other / Coronary Artery Disease / Heart Disease / Hypertension / Myocardial Infarction / Gout / Pneumonia, NOS.
- Timepoint category: Prior to Diagnosis; Immunosuppressive treatment type: Prednisone.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample RC-B666-NB1-A: Tissue type: Normal; Specimen type: Granulocytes; Preservation method: Frozen.
- Sample RC-B666-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
